Gene-level copy-number profile of tumor specimen TCGA-O2-A5IB-01A from TCGA case TCGA-O2-A5IB, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage III; Age at diagnosis: 71.8 years (26,211 days).
Specimen TCGA-O2-A5IB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.e28d237f-605e-4fed-8724-deca69be76d6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-O2-A5IB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7beaa0f6-3fb6-44b8-b9ac-a0d5a00e7703

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 15,298; copy number 2: 36,040; copy number 3: 5,636; copy number 4: 669; copy number 5: 2,167.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-O2-A5IB-01A-11D-A27J-01): tumor purity 0.93, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:71,289,769–71,305,853, 1 gene (within-gene range 0–1): FOXP1-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,167 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,923,317–178,484,147, 928 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr18:47,390–80,247,514, 1,239 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15,298. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
